Somatic mutation profile of tumor specimen ALCH-AFDS-TTP1-A (aliquot ALCH-AFDS-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AFDS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.2 years (27,840 days).
Specimen ALCH-AFDS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f61a33eb-5d85-4be5-adfd-37f29cb50e7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFDS-NB1-A (Blood Derived Normal), aliquot ALCH-AFDS-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b378b94c-0639-496d-bf7d-debdc85c813b

The open-access MAF lists 43 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Intron 3, Frame Shift Ins 2, 5'Flank 1, RNA 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 137/708 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 85/602 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762873545, COSV62788607, COSV62790642; called by muse, mutect2, varscan2
- CACNA2D3 | c.2044C>A p.P682T | Missense Mutation (SNP) | VAF 64/365 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV55540649; called by muse, mutect2, varscan2
- IAPP | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as rs761079012, COSV53714105; called by muse, mutect2, varscan2
- KCNH1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs902970026; called by muse, mutect2, varscan2
- NID2 | c.3491G>A p.R1164Q | Missense Mutation (SNP) | VAF 58/408 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.409); catalogued as rs769784950, COSV53493424; called by muse, mutect2, varscan2
- SEMA6D | c.3020C>T p.A1007V (on ENST00000316364 / NM_153618.2; = p.A945V on NM_020858.2) | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs557138877, COSV60384857; called by muse, mutect2, varscan2
- SEPTIN12 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51615491; called by muse, mutect2, varscan2
- SOS1 | c.806T>A p.M269K | Missense Mutation (SNP) | VAF 62/463 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as CM070275, CM074570, COSV67674247, COSV67676625; called by muse, mutect2, varscan2
- SPINK5 | c.2759G>A p.R920Q | Missense Mutation (SNP) | VAF 72/498 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.234); catalogued as rs371134163, COSV99806409; called by mutect2, varscan2
- ZNF91 | c.2296A>G p.R766G | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56093751; called by muse, mutect2, varscan2
- CCDC17 | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 76/527 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- COL9A1 | c.2404G>T p.G802C | Missense Mutation (SNP) | VAF 59/344 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFNA1 | c.120dup p.V41Cfs*5 | Frame Shift Ins (INS) | VAF 15/123 reads (12%) | called by mutect2, pindel, varscan2
- FAM120C | c.2380G>A p.A794T | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO9 | c.309dup p.E104Rfs*9 | Frame Shift Ins (INS) | VAF 14/110 reads (13%) | called by pindel, varscan2
- GLI2 | c.4094G>C p.R1365P (on ENST00000361492 / NM_001374353.1; = p.R1382P on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by mutect2, varscan2
- MRPL27 | c.224G>T p.W75L | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- NPC1 | c.3163C>G p.L1055V | Missense Mutation (SNP) | VAF 192/1186 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, varscan2
- NUP153 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 70/510 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PEAR1 | c.2278G>T p.G760C | Missense Mutation (SNP) | VAF 77/637 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBNO2 | c.3649G>T p.V1217L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SETD2 | c.4904G>T p.C1635F | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC37A3 | c.1339C>G p.L447V (on ENST00000326232 / NM_001363375.1; = p.S346C on NM_032295.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.074); called by muse, varscan2
- ZNF141 | c.1305T>G p.F435L | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.02); called by muse, varscan2
- ZNF398 | c.950C>G p.P317R (on ENST00000475153 / NM_170686.3; = p.P146R on NM_020781.4) | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DOCK8 | c.3027G>A p.R1009= | Silent (SNP) | VAF 68/377 reads (18%) | catalogued as rs1231234653; called by muse, mutect2, varscan2
- EIF5AL1 | c.117G>A p.K39= | Silent (SNP) | VAF 44/480 reads (9%) | catalogued as rs1354804074; called by muse, mutect2, varscan2
- FUCA2 | c.201C>T p.P67= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, varscan2
- HMCN1 | c.3390C>T p.L1130= | Silent (SNP) | VAF 86/570 reads (15%) | called by muse, mutect2, varscan2
- INCENP | c.396C>T p.A132= | Silent (SNP) | VAF 60/415 reads (14%) | catalogued as rs140463949, COSV53912922; called by muse, mutect2, varscan2
- MYH7 | c.1629C>G p.A543= | Silent (SNP) | VAF 30/167 reads (18%) | called by muse, mutect2, varscan2
- NPC1 | c.3432C>A p.L1144= | Silent (SNP) | VAF 168/1056 reads (16%) | catalogued as COSV99340224; called by muse, varscan2
- PLD5 | c.1152C>T p.F384= (on ENST00000442594; = p.F322= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/134 reads (16%) | called by muse, varscan2
- TMEM200C | c.444C>T p.S148= | Silent (SNP) | VAF 72/572 reads (13%) | catalogued as rs1262343224, COSV67310001; called by muse, mutect2
- VWA5B1 | c.87G>T p.L29= | Silent (SNP) | VAF 32/166 reads (19%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915378 C>T | 5'Flank (SNP) | VAF 52/322 reads (16%) | called by muse, mutect2, varscan2
- CIRBP | c.431+52C>T | Intron (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2
- EDRF1 | c.2371+161A>G | Intron (SNP) | VAF 8/146 reads (5%) | catalogued as rs1299179669; called by muse, mutect2
- RORA | c.197-61110G>A | Intron (SNP) | VAF 33/242 reads (14%) | catalogued as rs1329605907; called by muse, mutect2, varscan2
- SLC25A51P4 | n.620G>A | RNA (SNP) | VAF 50/403 reads (12%) | called by muse, mutect2, varscan2
- UTP4 | c.-24del | 5'UTR (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- WNT9B | chr17:46885101 G>T | 3'Flank (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
